Somatic mutation profile of tumor specimen TCGA-EL-A3ZL-01A (aliquot TCGA-EL-A3ZL-01A-11D-A23M-08) from TCGA case TCGA-EL-A3ZL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.6 years (12,649 days).
Specimen TCGA-EL-A3ZL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6909fe4a-cb8c-4ae8-884a-7525c5aaf682.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZL-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZL-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bbd8eb1-08de-420f-9bd3-5e64359a6dd9

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- EXT1 | c.1886A>T p.Y629F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100983586; called by muse, mutect2, varscan2
- GJA1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs753470523, COSV99246805; called by muse, mutect2, varscan2
- IGFBP1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99298638; called by muse, mutect2, varscan2
- MROH2B | c.3043G>A p.G1015S | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.144); catalogued as rs1211364496, COSV68181233, COSV68191170; called by muse, mutect2, varscan2
- PC | c.610A>G p.M204V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100852061; called by muse, mutect2, varscan2
- PRDX6 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100458407; called by muse, mutect2, varscan2
- DNAH10 | c.11244G>A p.L3748= (on ENST00000409039; = p.L3687= on NM_207437.3) | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV101292003; called by muse, mutect2, varscan2
- IL12B | c.393C>T p.C131= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs757355295, COSV51454192; called by muse, mutect2, varscan2
- MYH14 | c.3384A>G p.K1128= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99221826; called by muse, mutect2, varscan2
- PDE4A | c.690G>A p.L230= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99533667; called by muse, mutect2
- TNRC6C | c.1332G>A p.L444= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV100049513; called by muse, mutect2, varscan2
- COL14A1 | c.-2A>T | 5'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99918110; called by muse, mutect2, varscan2
- CR1 | c.487+15260G>T | Intron (SNP) | VAF 16/18 reads (89%) | called by mutect2, varscan2
